Somatic mutation profile of tumor specimen MBCProject_6246_T1_WES (aliquot MBCProject_6246_T1_WES_1) from CMI case MBCProject_6246, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 40.4 years (14,768 days).
Specimen MBCProject_6246_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b995371-cec7-4a6c-8dc2-384fe4cfb21c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6246_SALIVA (Saliva), aliquot MBCProject_6246_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/529d4e88-b7e0-4155-8e0e-47a052ad6efb

The open-access MAF lists 37 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Intron 4, 3'Flank 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 23/41 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOBR | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs977089132; called by muse, mutect2, varscan2
- BIN1 | c.736G>A p.A246T (on ENST00000316724 / NM_001320642.1; = p.A215T on NM_004305.4) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.955); catalogued as rs974115762, COSV99387705; called by muse, mutect2, varscan2
- CYFIP2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.692); catalogued as COSV59034919; called by muse, mutect2, varscan2
- FBXO32 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 145/417 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200573696, COSV54890035; called by muse, mutect2, varscan2
- RENBP | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs145748837; called by muse, mutect2, varscan2
- SECTM1 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.299); catalogued as rs1475595393; called by muse, mutect2, varscan2
- SPTA1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 81/783 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.065); catalogued as rs549232925, COSV104426832; called by muse, mutect2, varscan2
- TTYH2 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751567486, COSV53909013; called by muse, mutect2, varscan2
- BPTF | c.4325C>A p.S1442Y | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2
- CAD | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- EP300 | c.1929A>T p.E643D | Missense Mutation (SNP) | VAF 153/259 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FBXL15 | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXW10 | c.2902G>C p.E968Q | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, varscan2
- MAGEE2 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); called by muse, mutect2
- PDZK1 | c.197A>C p.E66A | Missense Mutation (SNP) | VAF 108/373 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PLEKHG4 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2
- SLC9C1 | c.2100T>G p.Y700* | Nonsense Mutation (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- TLK2 | c.1343A>G p.D448G (on ENST00000326270 / NM_001284333.2; = p.D426G on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/277 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TUSC1 | c.258C>A p.N86K | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- UCMA | c.69G>C p.E23D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- XKRX | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP13A3 | c.706C>T p.L236= | Silent (SNP) | VAF 88/279 reads (32%) | catalogued as COSV55463214; called by muse, mutect2, varscan2
- DHX15 | c.15C>T p.H5= | Silent (SNP) | VAF 47/231 reads (20%) | called by muse, mutect2, varscan2
- DOCK6 | c.219G>A p.R73= | Silent (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- KIFC1 | c.1449C>T p.G483= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs1271634529, COSV100997116; called by muse, mutect2, varscan2
- MALRD1 | c.5541A>G p.R1847= | Silent (SNP) | VAF 78/426 reads (18%) | called by muse, mutect2, varscan2
- MLXIPL | c.711G>A p.P237= | Silent (SNP) | VAF 60/241 reads (25%) | catalogued as rs781960833; called by muse, mutect2, varscan2
- MR1 | c.144G>A p.G48= | Silent (SNP) | VAF 152/301 reads (50%) | called by muse, mutect2, varscan2
- PLEKHH3 | c.2094G>T p.T698= | Silent (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- TET2 | c.3813C>T p.C1271= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs533538484, COSV54395761, COSV54418100, COSV54426906, COSV99480757; called by muse, mutect2, varscan2
- AP001267.5 | c.-799+5245A>G | Intron (SNP) | VAF 147/252 reads (58%) | called by muse, mutect2, varscan2
- ATIC | c.19+23C>G | Intron (SNP) | VAF 71/155 reads (46%) | called by muse, mutect2, varscan2
- EFCAB5 | c.2738-5057C>T | Intron (SNP) | VAF 26/166 reads (16%) | catalogued as rs1439794085; called by muse, mutect2, varscan2
- LINC02412 | n.962C>T | RNA (SNP) | VAF 80/222 reads (36%) | called by muse, mutect2, varscan2
- PXN | c.832-1277_832-1269del | Intron (DEL) | VAF 6/38 reads (16%) | catalogued as rs1022363219; called by mutect2, pindel
- USP34 | chr2:61184770 C>T | 3'Flank (SNP) | VAF 64/377 reads (17%) | called by muse, mutect2, varscan2
